Somatic mutation profile of tumor specimen TCGA-CR-7379-01A (aliquot TCGA-CR-7379-01A-11D-2012-08) from TCGA case TCGA-CR-7379, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 78.7 years (28,763 days).
Specimen TCGA-CR-7379-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01297409-7aba-4665-9c96-96d7223bd973.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7379-10A (Blood Derived Normal), aliquot TCGA-CR-7379-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0cecb66-155e-4588-831f-c566f996c464

The open-access MAF lists 137 somatic variants for this specimen: 90 protein-altering or splice-affecting, 45 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 45, Nonsense Mutation 9, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 19/46 reads (41%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- TP53 | c.408A>T p.Q136H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758781593, CM064342, COSV52979889, COSV52987518, COSV52988005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.10231C>T p.H3411Y | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV101447283; called by muse, mutect2, varscan2
- ACO1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273311415, COSV100008813; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4310C>G p.S1437C | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99720834, COSV99721816; called by muse, mutect2
- AHR | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54123813; called by muse, mutect2, varscan2
- ALS2 | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99970197; called by muse, mutect2, varscan2
- ARHGAP45 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs1294788367, COSV100491242; called by muse, mutect2, varscan2
- ARMCX3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs1257173965, COSV57870229; called by muse, mutect2, varscan2
- ASIC5 | c.1307T>A p.V436E | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV101611190; called by muse, mutect2, varscan2
- ATP12A | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as rs1388344681, COSV54516352; called by muse, mutect2, varscan2
- BNC1 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs189311441, COSV61758122; called by muse, mutect2, varscan2
- CASP8 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51847282; called by muse, mutect2, varscan2
- CDON | c.3307A>T p.I1103F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV99702188; called by muse, mutect2, varscan2
- CLASRP | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99674230; called by muse, mutect2, varscan2
- COL5A3 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53413305, COSV99319982; called by mutect2, varscan2
- DTX3 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs371981174, COSV99678394; called by muse, mutect2, varscan2
- EEF1AKNMT | c.316A>C p.T106P (on ENST00000361735 / NM_015935.5; = p.T20P on NM_014955.3) | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100676097; called by muse, mutect2, varscan2
- EPB42 | c.463C>T p.R155C (on ENST00000441366 / NM_001114134.2; = p.R185C on NM_000119.3) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs146473183; called by muse, mutect2, varscan2
- ERCC6L | c.2957C>G p.P986R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100559303; called by muse, mutect2, varscan2
- FAM171A1 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV65320542; called by muse, mutect2, varscan2
- FAM83H | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.914); catalogued as COSV101187098; called by muse, mutect2, varscan2
- FAT1 | c.2774C>G p.P925R | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101499697; called by muse, mutect2, varscan2
- FBXW7 | c.1576T>C p.W526R (on ENST00000281708 / NM_001349798.2; = p.W446R on NM_018315.5) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55922932; called by muse, mutect2, varscan2
- FOXR2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100189633; called by muse, mutect2, varscan2
- GFPT2 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1012796939, COSV99518203; called by muse, mutect2, varscan2
- HEATR5A | c.6023G>A p.R2008H | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs747281156, COSV101120733; called by muse, mutect2, varscan2
- HHLA2 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100755552; called by muse, mutect2, varscan2
- HTR2C | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs781954366, COSV52202303; called by muse, mutect2, varscan2
- HYDIN | c.1164G>C p.Q388H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV99866080; called by mutect2, varscan2
- IGSF10 | c.5337G>T p.W1779C | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99201151; called by muse, mutect2, varscan2
- INTS8 | c.1404G>C p.L468F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV100569547; called by muse, mutect2
- ITK | c.987C>T p.G329= | Splice Region (SNP) | VAF 9/36 reads (25%) | catalogued as COSV101439912; called by muse, mutect2, varscan2
- KERA | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99899625; called by muse, mutect2, varscan2
- KMT2D | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99986640; called by muse, mutect2, varscan2
- LANCL3 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101065795; called by muse, mutect2
- LBP | c.689A>T p.Y230F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV99461457; called by muse, mutect2, varscan2
- LCOR | c.4294C>T p.P1432S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV99617288; called by muse, mutect2, varscan2
- LMF2 | c.1240T>C p.F414L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99327843; called by muse, mutect2, varscan2
- MACC1 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.424); catalogued as COSV100256394; called by muse, mutect2, varscan2
- MED13L | c.2845A>G p.M949V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs760709095, COSV99930566; called by muse, mutect2, varscan2
- MED23 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs776987373, COSV63435392; called by muse, mutect2, varscan2
- MPP1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.048); catalogued as rs146674414, COSV101053773; called by muse, mutect2, varscan2
- MUC16 | c.6307C>T p.Q2103* | Nonsense Mutation (SNP) | VAF 22/274 reads (8%) | catalogued as rs962733190, COSV101202185; called by muse, mutect2
- NAA25 | c.1069A>T p.K357* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99928174; called by muse, mutect2, varscan2
- NCOR2 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100658033; called by muse, mutect2, varscan2
- NECAB1 | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV101341250; called by muse, varscan2
- NEUROD6 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV51772165, COSV99774244; called by muse, mutect2, varscan2
- NOTCH1 | c.5625T>A p.N1875K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV99492709; called by muse, mutect2, varscan2
- OGA | c.1752G>A p.W584* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | catalogued as COSV100761992; called by muse, mutect2, varscan2
- OTP | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1308245059, COSV100119931, COSV60569560; called by muse, mutect2, varscan2
- PGM5 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs201672908, COSV67168317; called by muse, mutect2, varscan2
- PPFIA2 | c.3176T>C p.L1059P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335671; called by muse, varscan2
- PPFIBP1 | c.2536G>A p.V846I (on ENST00000318304 / NM_177444.3; = p.V840I on NM_003622.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs539499516, COSV57299002; called by muse, mutect2, varscan2
- PRDM9 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99691509; called by muse, mutect2, varscan2
- PRMT3 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV100424327; called by muse, mutect2, varscan2
- PSD4 | c.1654T>A p.S552T | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.15); catalogued as COSV99831541; called by muse, mutect2, varscan2
- PTPRF | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780147204, COSV63443031, COSV63447137; called by muse, mutect2, varscan2
- PTPRU | c.4009C>T p.R1337W | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs996914255, COSV100113982; called by muse, mutect2, varscan2
- RPL10L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764186971, COSV100022301; called by muse, mutect2, varscan2
- RUNDC1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs199952607, COSV64512484; called by muse, mutect2, varscan2
- SELP | c.971G>A p.C324Y | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99741375; called by muse, mutect2, varscan2
- SETMAR | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV100740924; called by muse, mutect2, varscan2
- SFR1 | c.104C>T p.S35L (on ENST00000369727 / NM_001002759.1; = p.S22L on NM_145247.4) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV60478771; called by muse, mutect2, varscan2
- SHC3 | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs773476747, COSV101012100; called by muse, mutect2, varscan2
- SNTG1 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs778737467, COSV52423447, COSV99385799; called by muse, mutect2, varscan2
- SOCS4 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV100216399; called by muse, mutect2, varscan2
- SORCS1 | c.2536G>A p.V846I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs756255470, COSV53891460; called by muse, mutect2, varscan2
- SPATA17 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100861262; called by muse, mutect2, varscan2
- SULF1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 28/142 reads (20%) | catalogued as COSV52686680, COSV99484658; called by muse, mutect2, varscan2
- SUV39H1 | c.909C>A p.Y303* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100551894; called by muse, mutect2, varscan2
- SV2B | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs1230570278, COSV100371180; called by muse, mutect2, varscan2
- SYNRG | c.3706C>T p.R1236W | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200645501; called by muse, mutect2, varscan2
- SYTL1 | c.971G>A p.R324Q (on ENST00000543823; = p.R312Q on NM_032872.3) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs761181092, COSV58872884; called by muse, mutect2, varscan2
- TAF4B | c.356T>A p.I119N | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99301184; called by muse, mutect2, varscan2
- TENM1 | c.6695G>C p.G2232A | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100951275, COSV100951323; called by muse, mutect2, varscan2
- TMC4 | c.1358C>T p.T453I (on ENST00000617472 / NM_001145303.3; = p.T447I on NM_144686.4) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99714235; called by muse, mutect2, varscan2
- TPD52L3 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.522); catalogued as rs1357675099, COSV100096182; called by muse, mutect2, varscan2
- TRAM1 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51599219; called by muse, mutect2, varscan2
- TTN | c.6760G>A p.V2254I (on ENST00000591111; = p.V2208I on NM_003319.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | PolyPhen benign (0); catalogued as rs1401971730, COSV100635367; called by muse, mutect2, varscan2
- VSIG4 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs1157278270, COSV101038369, COSV66074625; called by muse, mutect2, varscan2
- WDR62 | c.1289C>T p.T430I | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99544406; called by muse, mutect2, varscan2
- ZBTB10 | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV100990503; called by muse, mutect2
- ZMYM3 | c.3880C>T p.R1294C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879255361, COSV100078128; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF99 | c.1280G>T p.C427F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68055911; called by muse, mutect2, varscan2
- FBXW7 | c.765_769dup p.I257Nfs*11 (on ENST00000281708 / NM_001349798.2; = p.I177Nfs*11 on NM_018315.5) | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- ITGB3 | c.447del p.M150* | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- VN1R5 | c.996A>C p.Q332H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- WASHC2C | c.2692C>T p.Q898* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2
- ZNF654 | c.1930_1932del p.T644del | In Frame Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- ACSM5 | c.945C>A p.T315= | Silent (SNP) | VAF 67/246 reads (27%) | catalogued as COSV100089726; called by muse, mutect2, varscan2
- ASB18 | c.192C>T p.T64= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1169533543, COSV68960320; called by muse, mutect2, varscan2
- BLM | c.3426C>T p.A1142= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs147148171; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALCOCO1 | c.912G>A p.K304= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100017551; called by muse, mutect2, varscan2
- CCDC107 | c.228C>G p.V76= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100526405; called by muse, mutect2, varscan2
- CYP11B2 | c.33G>A p.V11= | Silent (SNP) | VAF 44/240 reads (18%) | catalogued as COSV100011476; called by muse, mutect2, varscan2
- DDX20 | c.600G>A p.L200= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV100865983; called by muse, mutect2, varscan2
- EIF2S1 | c.468A>C p.A156= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV99833273; called by muse, mutect2, varscan2
- ERBB4 | c.1266C>T p.T422= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV99636002, COSV99636047; called by muse, mutect2, varscan2
- EXPH5 | c.5272C>T p.L1758= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99762402; called by muse, mutect2, varscan2
- FANCB | c.2325T>G p.S775= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100146723; called by muse, mutect2, varscan2
- FAT4 | c.4104C>T p.N1368= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV101272925, COSV67887765; called by muse, mutect2, varscan2
- FBN1 | c.4698G>C p.L1566= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV100356643; called by muse, mutect2, varscan2
- FOXG1 | c.1272G>A p.P424= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs757300535, COSV57397063; called by muse, mutect2, varscan2
- HGS | c.639G>A p.E213= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs1336189886, COSV100230815, COSV100230862; called by muse, mutect2, varscan2
- IL17REL | c.72G>A p.A24= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs374166463; called by muse, mutect2, varscan2
- KLHL14 | c.276G>A p.P92= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs769811020, COSV100809372; called by muse, mutect2, varscan2
- LANCL3 | c.291G>A p.K97= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101065797; called by muse, mutect2
- LCOR | c.2970T>A p.A990= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99617287; called by muse, mutect2, varscan2
- LRFN2 | c.1185C>T p.R395= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100600059; called by muse, mutect2, varscan2
- MADD | c.1008G>C p.V336= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100212144; called by muse, mutect2, varscan2
- MAGEA4 | c.567C>G p.G189= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as COSV99367769; called by muse, mutect2
- MAN2B1 | c.1953C>T p.N651= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs547133035, COSV55471393; called by muse, mutect2, varscan2
- MKI67 | c.960A>G p.G320= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100897096; called by muse, mutect2, varscan2
- MRTFA | c.1482T>C p.P494= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100844468; called by muse, mutect2, varscan2
- MSX1 | c.801G>T p.A267= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101235785; called by muse, mutect2, varscan2
- NXF3 | c.654G>A p.Q218= | Silent (SNP) | VAF 36/380 reads (9%) | catalogued as COSV67705106; called by muse, mutect2
- OR52D1 | c.48C>T p.F16= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100495363; called by muse, mutect2, varscan2
- PHF3 | c.5223G>A p.E1741= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100014193; called by muse, mutect2, varscan2
- PLEC | c.552C>A p.T184= (on ENST00000322810 / NM_201380.4; = p.T74= on NM_000445.5) | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs782244901, COSV100519990; called by muse, mutect2, varscan2
- PRH2 | c.81C>T p.D27= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs1130408, COSV101113359; called by muse, mutect2, varscan2
- PRKD1 | c.2655C>A p.I885= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV100121833; called by muse, mutect2, varscan2
- RB1 | c.1701A>T p.S567= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99927305; called by muse, mutect2
- RBP3 | c.2127G>A p.V709= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- RDH8 | c.351G>T p.G117= (on ENST00000651512; = p.G97= on NM_015725.4) | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV99408846; called by muse, mutect2, varscan2
- SLMAP | c.1449C>T p.L483= (on ENST00000428312 / NM_001377924.1; = p.L545= on NM_007159.5) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99909427; called by muse, mutect2, varscan2
- SPPL2A | c.615T>C p.D205= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1183234957, COSV99961904; called by muse, mutect2, varscan2
- TMC7 | c.969G>A p.A323= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs762671714, COSV100432914; called by muse, mutect2, varscan2
- TTC39B | c.777C>T p.N259= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs778543697, COSV99896367; called by mutect2, varscan2
- WDR17 | c.2667G>A p.V889= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV54574009; called by muse, mutect2, varscan2
- ZBTB1 | c.852C>T p.Y284= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100704264; called by muse, mutect2, varscan2
- ZIM3 | c.222G>A p.V74= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV99518870; called by muse, mutect2, varscan2
- ZMYND15 | c.1761C>G p.G587= (on ENST00000433935 / NM_001136046.3; = p.G548= on NM_032265.2) | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV99351940; called by muse, mutect2
- ZNF423 | c.147G>A p.A49= (on ENST00000563137 / NM_001379286.1; = p.A41= on NM_015069.4) | Silent (SNP) | VAF 44/321 reads (14%) | catalogued as rs566780634, COSV52182968; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZPBP | c.261G>C p.T87= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs769864652, COSV50431511, COSV99250728; called by muse, mutect2, varscan2
- MIR548M | n.12G>C | RNA (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- NTNG1 | c.-1G>A | 5'UTR (SNP) | VAF 42/90 reads (47%) | catalogued as COSV99640166; called by muse, mutect2, varscan2
